Somatic mutation profile of tumor specimen TCGA-WB-A81M-01A (aliquot TCGA-WB-A81M-01A-11D-A35I-08) from TCGA case TCGA-WB-A81M, project TCGA-PCPG (Pheochromocytoma and Paraganglioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Pheochromocytoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 42.5 years (15,505 days).
Specimen TCGA-WB-A81M-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f022dfe3-03f0-44a6-a1d8-3dcd4d0c8f20.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-WB-A81M-10A (Blood Derived Normal), aliquot TCGA-WB-A81M-10A-01D-A35G-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9c1be2dc-25cb-492b-9c98-4a2a4ebebf68

The open-access MAF lists 9 somatic variants for this specimen: 6 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 5, Silent 3, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FAF1 | c.688A>G p.I230V | Missense Mutation (SNP) | VAF 28/34 reads (82%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.978); catalogued as COSV100875151; called by muse, mutect2, varscan2
- CSDE1 | c.1323_1324insG p.K442Efs*4 (on ENST00000358528 / NM_001007553.3; = p.K411Efs*4 on NM_007158.6) | Frame Shift Ins (INS) | VAF 30/49 reads (61%) | called by mutect2, pindel, varscan2
- PIF1 | c.1742C>T p.A581V | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ROBO3 | c.761T>C p.V254A | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- SALL4 | c.1712G>A p.C571Y | Missense Mutation (SNP) | VAF 52/114 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SYTL4 | c.793A>T p.I265F | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT tolerated (0.68); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- EHD2 | c.1071G>A p.Q357= | Silent (SNP) | VAF 16/38 reads (42%) | called by mutect2, varscan2
- KBTBD8 | c.984G>T p.G328= | Silent (SNP) | VAF 12/130 reads (9%) | called by muse, mutect2
- PANX3 | c.553C>A p.R185= | Silent (SNP) | VAF 23/54 reads (43%) | called by muse, mutect2, varscan2
